FM case AD9360 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Small intestine.
https://portal.gdc.cancer.gov/cases/0fa757b0-2087-45c8-9990-d7056d7293c2

Female, 70.2 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the duodenum; primary biopsied or resected from the duodenum. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
